Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4355, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4355-01A (Primary Tumor).

[page 1 of 4]
.....

Clinical Diagnosis & History:

History of metastatic renal cell carcinoma with left renal mass.

Specimens Submitted:

1: Kidney and adrenal, left; radical nephrectomy

DIAGNOSIS:

1. Kidney and adrenal, left; radical nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
with large foci of necrosis

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 13.0 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia
Involves renal hilar fat

Renal Vein Invasion:

Not identified
However, the tumor invades muscular veins in the renal sinus

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild arteriosclerotic changes and benign cortical cysts

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

.....

[page 2 of 4]
Clinical Diagnosis & History:

History of metastatic renal cell carcinoma with left renal mass.

Specimens Submitted:

1: Kidney and adrenal, left; radical nephrectomy

DIAGNOSIS:

1. Kidney and adrenal, left; radical nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
with large foci of necrosis

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 13.0 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia
Involves renal hilar fat

Renal Vein Invasion:

Not identified
However, the tumor invades muscular veins in the renal sinus

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild arteriosclerotic changes and benign cortical cysts

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 3 of 4]
....

Clinical Diagnosis & History:

History of metastatic renal cell carcinoma with left renal mass.

Specimens Submitted:

1: Kidney and adrenal, left; radical nephrectomy

DIAGNOSIS:

1. Kidney and adrenal, left; radical nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
with large foci of necrosis

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 13.0 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia
Involves renal hilar fat

Renal Vein Invasion:

Not identified
However, the tumor invades muscular veins in the renal sinus

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild arteriosclerotic changes and benign cortical cysts

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 4 of 4]
Gross Description:

1). The specimen is received fresh labeled "left kidney and adrenal" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing [REDACTED]. The kidney measures 10.0 x 5.0 x 4.0 cm. The attached ureter measures 5.0 cm in length and 0.5 cm in diameter. The attached renal vein measures 2.5 cm in length and 2.5 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified, measuring 6.0 x 5.0 x 2.0 cm. The kidney is inked black and bivalved to reveal an ill-defined yellow orange mass extending from the lower pole of the kidney measuring 13.0 x 13.0 x 9.2 cm. The lesion distorts the kidney cortex without grossly invading the perinephric adipose tissue. Serial sections through the mass show areas of fibrosis, mucinous degeneration, necrosis and hemorrhage. No gross invasion into the sinus that is identified, however, gross extension into the hilar fat cannot be assessed. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.5 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections. A photograph is taken.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

TC - tumor with capsule and perinephric fat

TV- tumor to vein

K -- representative sections kidney

AD -- adrenal gland

Summary of Sections:

Part 1: Kidney and adrenal, left; radical nephrectomy

Block	Sect. Site	PCs
1	ad	1
2	k	2
6	t	6
3	tc	3
2	thf	2
1	tk	1
1	tsf	1
1	tv	1
1	uvm	1

Source: NCI Genomic Data Commons file a359b2da-d3f4-4f3a-82a4-53da7ff65f81 (TCGA-BP-4355.BDB3C920-2844-4FE3-B05F-1A281B4F8886.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).